Somatic mutation profile of tumor specimen C3N-03780-01 (aliquot CPT0246940006) from CPTAC case C3N-03780, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.2 years (25,275 days).
Specimen C3N-03780-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e028f2b9-35d6-4c86-b31f-72a0e3bc0e2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03780-31 (Blood Derived Normal), aliquot CPT0246980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5532ed6-2707-4846-86e2-418b9e0ba096

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Intron 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 48/410 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1572G>T p.W524C | Missense Mutation (SNP) | VAF 40/515 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV61685820, COSV61686227, COSV61686374; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/481 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- AP002495.1 | c.508C>T p.R170C (on ENST00000528511; = p.R101C on NM_001375848.1) | Missense Mutation (SNP) | VAF 37/475 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs766087889; called by muse, mutect2
- ATP2B3 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 36/425 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs895866699; called by muse, mutect2
- CCDC38 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 37/384 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs771269053; called by muse, mutect2
- EDC3 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 26/562 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as COSV59341642; called by muse, mutect2
- ENPP2 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs759807131; called by muse, mutect2
- EPS8L3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 31/404 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs757406657; called by muse, mutect2
- GRM1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs776187845, COSV51185332; called by muse, mutect2
- IKBKB | c.2231C>T p.T744M | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs138183879; called by muse, mutect2
- LRP1B | c.12595G>A p.G4199R | Missense Mutation (SNP) | VAF 35/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865839359, COSV67275984; called by muse, mutect2
- MTPAP | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 46/788 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV53932697; called by muse, mutect2
- NEFH | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs1393330476; called by muse, mutect2, varscan2
- NIN | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 23/401 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768423014, COSV55396464; called by muse, mutect2
- OR2J3 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs762835534, COSV101013561, COSV65848968; called by muse, mutect2, varscan2
- PPIG | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs748608521, COSV53646808; called by muse, mutect2
- SLIT1 | c.3188C>T p.T1063I | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.623); catalogued as rs1041420300; called by muse, mutect2
- SORCS1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 26/566 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as COSV53881441, COSV53883119; called by muse, mutect2
- SVEP1 | c.8519C>A p.A2840D | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.096); catalogued as rs767320138; called by muse, mutect2, varscan2
- TTC21B | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs151309609; ClinVar: uncertain significance; called by muse, mutect2
- ZFAT | c.3491A>G p.Q1164R | Missense Mutation (SNP) | VAF 66/465 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs750068172; called by muse, mutect2, varscan2
- BCAS3 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- DHX29 | c.2901G>T p.E967D | Missense Mutation (SNP) | VAF 38/493 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- FRMD7 | c.1352A>C p.K451T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.345); called by muse, mutect2
- HELZ2 | c.6827A>G p.Q2276R (on ENST00000467148 / NM_001037335.2; = p.Q1707R on NM_033405.3) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.029); called by muse, mutect2
- JPH3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); called by muse, mutect2
- MAP2K4 | c.482T>A p.I161N | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- POLR2B | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNS3 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 31/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPM6A | c.90G>A p.L30= | Silent (SNP) | VAF 22/388 reads (6%) | catalogued as COSV54548561, COSV54554692; called by muse, mutect2
- HOXD13 | c.138G>A p.A46= | Silent (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- ITIH4 | c.669A>G p.Q223= | Silent (SNP) | VAF 21/275 reads (8%) | called by muse, mutect2
- MAGEL2 | c.765G>A p.P255= | Silent (SNP) | VAF 29/367 reads (8%) | catalogued as rs760536434; called by muse, mutect2
- MAP2K4 | c.483T>A p.I161= | Silent (SNP) | VAF 26/319 reads (8%) | catalogued as COSV100796121; called by muse, mutect2
- MYO7B | c.2902C>T p.L968= | Silent (SNP) | VAF 54/625 reads (9%) | catalogued as COSV67352860; called by muse, mutect2
- OR52M1 | c.78C>T p.H26= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs559376682, COSV64171311, COSV64171853; called by muse, mutect2
- UBR5 | c.2859A>G p.A953= | Silent (SNP) | VAF 40/323 reads (12%) | called by muse, mutect2, varscan2
- ZMYM2 | c.3006A>G p.P1002= | Silent (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- AC005863.1 | n.162C>T | RNA (SNP) | VAF 30/380 reads (8%) | catalogued as rs1380304977; called by muse, mutect2
- AP001993.1 | n.3385T>G | RNA (SNP) | VAF 24/366 reads (7%) | called by muse, mutect2
- LIMCH1 | c.936-6089G>A | Intron (SNP) | VAF 50/614 reads (8%) | catalogued as rs1055359702; called by muse, mutect2
- RYR1 | c.10440+20A>G | Intron (SNP) | VAF 41/466 reads (9%) | called by muse, mutect2
